Somatic mutation profile of tumor specimen C3L-03642-01 (aliquot CPT0216820006) from CPTAC case C3L-03642, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IA3; Tumor grade: G2; Age at diagnosis: 64.0 years (23,384 days).
Specimen C3L-03642-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a4db2f1a-a409-436f-974e-e279fb048d01.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-03642-31 (Blood Derived Normal), aliquot CPT0217680002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/939e3323-088c-4d12-bcbb-c81467c1dca9

The open-access MAF lists 482 somatic variants for this specimen: 322 protein-altering or splice-affecting, 103 silent, 57 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 276, Silent 103, Intron 30, Nonsense Mutation 24, RNA 10, Splice Site 9, 3'UTR 8, Frame Shift Del 6, 5'UTR 6, Splice Region 5, 3'Flank 2, Translation Start Site 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CFTR | c.3922G>T p.E1308* | Nonsense Mutation (SNP) | VAF 43/245 reads (18%) | catalogued as rs397508643, CM972963, COSV50080247; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- KRAS | c.64C>A p.Q22K | Missense Mutation (SNP) | VAF 314/458 reads (69%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as rs121913236, CM070964, COSV55526911, COSV55779357; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ACR | c.790del p.V264* | Frame Shift Del (DEL) | VAF 34/232 reads (15%) | catalogued as rs762191835; called by mutect2, pindel, varscan2
- ADAM28 | c.1589C>T p.S530L | Missense Mutation (SNP) | VAF 25/108 reads (23%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.946); catalogued as COSV56102346; called by muse, mutect2, varscan2
- AKAP6 | c.485G>C p.R162P | Missense Mutation (SNP) | VAF 29/236 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55216527; called by muse, mutect2, varscan2
- AMER3 | c.1114C>A p.P372T | Missense Mutation (SNP) | VAF 120/389 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.73); catalogued as rs1389263422; called by muse, mutect2, varscan2
- AMY2A | c.654G>A p.W218* | Nonsense Mutation (SNP) | VAF 104/1171 reads (9%) | catalogued as rs1237825167, COSV70214980; called by muse, mutect2
- ARHGAP44 | c.1483G>T p.A495S | Missense Mutation (SNP) | VAF 164/474 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.898); catalogued as COSV52393072; called by muse, mutect2, varscan2
- ARHGDIA | c.371C>T p.S124F | Missense Mutation (SNP) | VAF 15/446 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53907490; called by muse, mutect2
- BCL11B | c.802C>T p.P268S (on ENST00000357195 / NM_001282237.2; = p.P197S on NM_022898.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 21/144 reads (15%) | SIFT tolerated (0.32); PolyPhen benign (0.418); catalogued as COSV61733088; called by muse, mutect2, varscan2
- BTBD8 | c.3257G>T p.S1086I (on ENST00000636805 / NM_001376131.1; = p.S573I on NM_015237.4) | Missense Mutation (SNP) | VAF 77/264 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.104); catalogued as COSV64883566; called by muse, mutect2, varscan2
- C14orf39 | c.1100C>G p.S367W | Missense Mutation (SNP) | VAF 56/231 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.292); catalogued as COSV58780382; called by muse, mutect2, varscan2
- C20orf141 | c.428C>T p.P143L | Missense Mutation (SNP) | VAF 35/275 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs181014957, COSV100730151, COSV63028787; called by muse, mutect2, varscan2
- C4orf50 | c.661C>A p.R221S (on ENST00000324058; = p.R1453S on NM_001364689.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 34/192 reads (18%) | SIFT tolerated (0.54); PolyPhen benign (0.003); catalogued as COSV60689457; called by muse, mutect2, varscan2
- CARD11 | c.637G>C p.E213Q | Missense Mutation (SNP) | VAF 77/314 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.382); catalogued as rs1375885805, COSV62717222; called by muse, mutect2, varscan2
- CDH7 | c.2225C>G p.A742G | Missense Mutation (SNP) | VAF 52/281 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59883836; called by muse, mutect2, varscan2
- CFAP410 | c.77+1G>A p.X26_splice | Splice Site (SNP) | VAF 34/184 reads (18%) | catalogued as rs745732992; called by muse, mutect2, varscan2
- COL1A1 | c.2107C>T p.P703S | Missense Mutation (SNP) | VAF 21/688 reads (3%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.847); catalogued as rs1339321096, COSV56802693; called by muse, mutect2
- CSMD2 | c.71A>G p.Q24R | Missense Mutation (SNP) | VAF 39/317 reads (12%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.885); catalogued as rs749396007, COSV53874194; called by muse, mutect2, varscan2
- CSMD3 | c.1305A>G p.I435M | Missense Mutation (SNP) | VAF 27/118 reads (23%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.948); catalogued as rs1300537340; called by muse, mutect2, varscan2
- DACH2 | c.634C>A p.P212T | Missense Mutation (SNP) | VAF 28/110 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.933); catalogued as COSV64161713, COSV64165230; called by muse, mutect2, varscan2
- DEPDC5 | c.1166G>A p.R389H | Missense Mutation (SNP) | VAF 39/189 reads (21%) | SIFT tolerated (0.58); PolyPhen benign (0.003); catalogued as rs768332862; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DGKI | c.910C>A p.H304N | Missense Mutation (SNP) | VAF 58/189 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.484); catalogued as COSV55976181; called by muse, mutect2, varscan2
- DNAH10 | c.12070C>T p.R4024C (on ENST00000409039; = p.R3963C on NM_207437.3) | Missense Mutation (SNP) | VAF 13/359 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs755346965, CM153153; called by muse, mutect2
- DNAH5 | c.10213G>T p.G3405C | Missense Mutation (SNP) | VAF 56/488 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54233059; called by muse, mutect2, varscan2
- DNAH9 | c.10047C>A p.N3349K | Missense Mutation (SNP) | VAF 18/156 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.739); catalogued as rs747192728; called by muse, mutect2, varscan2
- ESYT2 | c.1261G>T p.G421C (on ENST00000613624; = p.G345C on NM_020728.3) | Missense Mutation (SNP) | VAF 31/148 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51750160; called by muse, mutect2, varscan2
- FAM171A1 | c.215G>A p.G72D | Missense Mutation (SNP) | VAF 128/502 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100968318; called by muse, mutect2, varscan2
- FOXO4 | c.289C>T p.R97C | Missense Mutation (SNP) | VAF 77/151 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.702); catalogued as COSV58576481; called by muse, varscan2
- FRMPD2 | c.1686G>T p.E562D | Missense Mutation (SNP) | VAF 29/325 reads (9%) | SIFT tolerated (0.38); PolyPhen benign (0.006); catalogued as rs369493205, COSV59719972; called by muse, mutect2
- GFRAL | c.476G>C p.G159A | Missense Mutation (SNP) | VAF 9/236 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.604); catalogued as COSV61229621; called by muse, mutect2
- GLIS1 | c.526G>A p.G176S | Missense Mutation (SNP) | VAF 78/216 reads (36%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs1196050830; called by muse, mutect2, varscan2
- GPR174 | c.555G>T p.M185I | Missense Mutation (SNP) | VAF 55/198 reads (28%) | SIFT tolerated (0.11); PolyPhen benign (0.081); catalogued as COSV52132111; called by muse, mutect2, varscan2
- GRAP | c.595C>T p.R199W | Missense Mutation (SNP) | VAF 39/187 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.803); catalogued as rs774325073; called by muse, mutect2, varscan2
- GRID2 | c.404G>T p.R135L | Missense Mutation (SNP) | VAF 137/476 reads (29%) | SIFT tolerated (0.27); PolyPhen benign (0.118); catalogued as COSV99941706; called by muse, mutect2, varscan2
- GRK4 | c.1030C>T p.R344* (on ENST00000398052 / NM_182982.3; = p.R312* on NM_005307.3) | Nonsense Mutation (SNP) | VAF 50/306 reads (16%) | catalogued as rs760891038, COSV61668476; called by muse, mutect2, varscan2
- GSDME | c.143G>T p.R48I | Missense Mutation (SNP) | VAF 56/582 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.708); catalogued as rs188664289, COSV99048716; called by muse, mutect2
- HCN1 | c.1771C>A p.L591I | Missense Mutation (SNP) | VAF 102/391 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.309); catalogued as COSV57522694; called by muse, mutect2, varscan2
- HOXA3 | c.679C>A p.L227M | Missense Mutation (SNP) | VAF 46/516 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100415530; called by muse, mutect2
- HOXA6 | c.272C>T p.S91L | Missense Mutation (SNP) | VAF 72/509 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.153); catalogued as COSV56071920; called by muse, mutect2, varscan2
- IBA57 | c.635G>T p.R212L | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.069); catalogued as rs763087570; called by muse, mutect2, varscan2
- JAKMIP3 | c.1984A>G p.I662V | Missense Mutation (SNP) | VAF 60/217 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.189); catalogued as COSV53825920; called by muse, mutect2, varscan2
- KCNH1 | c.631T>A p.L211I | Missense Mutation (SNP) | VAF 8/146 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1045681016; called by muse, mutect2
- KCNK2 | c.151G>A p.D51N (on ENST00000444842 / NM_001017425.3; = p.D36N on NM_014217.4) | Missense Mutation (SNP) | VAF 48/440 reads (11%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.199); catalogued as COSV67202987; called by muse, mutect2, varscan2
- KNDC1 | c.2975C>T p.S992L | Missense Mutation (SNP) | VAF 40/156 reads (26%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as rs776156819; called by muse, varscan2
- KTN1 | c.2961G>T p.Q987H | Missense Mutation (SNP) | VAF 20/104 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); catalogued as COSV101255448; called by muse, mutect2, varscan2
- LAMA2 | c.1196G>T p.R399I | Missense Mutation (SNP) | VAF 98/324 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV69000846; called by muse, mutect2, varscan2
- LAMA2 | c.2749C>A p.P917T | Missense Mutation (SNP) | VAF 40/391 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.922); catalogued as rs765699885; called by muse, mutect2, varscan2
- LAMC3 | c.1938C>T p.A646= | Splice Region (SNP) | VAF 93/416 reads (22%) | catalogued as rs377175197, COSV100736156; called by muse, mutect2, varscan2
- LAMC3 | c.1975G>T p.A659S | Missense Mutation (SNP) | VAF 60/411 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs141075974; called by muse, mutect2, varscan2
- LCE1C | c.344G>T p.G115V | Missense Mutation (SNP) | VAF 20/99 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV64219060; called by muse, mutect2, varscan2
- LRFN5 | c.1429G>T p.A477S | Missense Mutation (SNP) | VAF 54/287 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV53244532; called by muse, mutect2, varscan2
- LTBP1 | c.1831G>T p.E611* (on ENST00000404816 / NM_206943.4; = p.E285* on NM_000627.4) | Nonsense Mutation (SNP) | VAF 60/216 reads (28%) | catalogued as COSV63184777; called by muse, mutect2, varscan2
- MAGEC1 | c.2899G>C p.E967Q | Missense Mutation (SNP) | VAF 9/162 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.913); catalogued as COSV99596438; called by muse, mutect2
- MASTL | c.190G>T p.V64F | Missense Mutation (SNP) | VAF 42/266 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.925); catalogued as rs746273505; called by muse, mutect2, varscan2
- MBD1 | c.1597G>T p.G533C (on ENST00000269468 / NM_001323950.1; = p.G431C on NM_002384.2) | Missense Mutation (SNP) | VAF 16/384 reads (4%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.681); catalogued as COSV99495806; called by muse, mutect2
- MEGF11 | c.2964A>G p.I988M | Missense Mutation (SNP) | VAF 68/170 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.564); catalogued as rs756283166, COSV56561509; called by muse, mutect2, varscan2
- MTARC1 | c.531del p.Y178Tfs*18 | Frame Shift Del (DEL) | VAF 32/299 reads (11%) | catalogued as COSV100856220; called by mutect2, pindel, varscan2
- MYH7 | c.5135G>T p.R1712L | Missense Mutation (SNP) | VAF 171/697 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as CM114765, COSV62516288; called by muse, mutect2, varscan2
- MYO1H | c.166C>T p.L56F | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60448634; called by muse, mutect2
- MYO1H | c.2390G>A p.R797Q | Missense Mutation (SNP) | VAF 19/192 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.117); catalogued as rs1224296592, COSV100184014, COSV100184055; called by muse, mutect2, varscan2
- NEXMIF | c.2657G>T p.R886I | Missense Mutation (SNP) | VAF 104/206 reads (50%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV50179536; called by muse, varscan2
- NLGN4X | c.1143C>A p.D381E | Missense Mutation (SNP) | VAF 66/304 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as COSV52042984, COSV99319681; called by muse, mutect2, varscan2
- NLRP1 | c.1416G>T p.Q472H | Missense Mutation (SNP) | VAF 10/271 reads (4%) | SIFT tolerated (0.23); PolyPhen benign (0.062); catalogued as COSV52559035; called by muse, mutect2
- NPC1L1 | c.2737G>A p.E913K | Missense Mutation (SNP) | VAF 69/416 reads (17%) | SIFT tolerated (0.9); PolyPhen benign (0.014); catalogued as rs756628304, COSV56923389; called by muse, mutect2, varscan2
- NPIPB15 | c.157T>A p.S53T | Missense Mutation (SNP) | VAF 46/731 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.889); catalogued as rs750886938; called by muse, mutect2
- NPR3 | c.1273G>T p.E425* | Nonsense Mutation (SNP) | VAF 30/220 reads (14%) | catalogued as COSV99422489; called by muse, mutect2, varscan2
- NTNG1 | c.308C>A p.P103H | Missense Mutation (SNP) | VAF 28/198 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53984793; called by muse, mutect2, varscan2
- OR2W1 | c.805G>A p.D269N | Missense Mutation (SNP) | VAF 10/136 reads (7%) | SIFT tolerated (0.16); PolyPhen benign (0.052); catalogued as rs774358264; called by muse, mutect2
- OR51E2 | c.814C>T p.R272C | Missense Mutation (SNP) | VAF 92/532 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.606); catalogued as rs541160396, COSV67808453; called by muse, mutect2, varscan2
- OR6P1 | c.512C>A p.P171H | Missense Mutation (SNP) | VAF 86/325 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.8); catalogued as rs1443699549, COSV104402229; called by muse, mutect2, varscan2
- OR9Q1 | c.730C>A p.L244I | Missense Mutation (SNP) | VAF 27/101 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.284); catalogued as COSV59042533; called by muse, mutect2, varscan2
- PAPPA | c.2054C>A p.T685K | Missense Mutation (SNP) | VAF 41/263 reads (16%) | SIFT tolerated (0.18); PolyPhen benign (0.081); catalogued as COSV60292291; called by muse, mutect2, varscan2
- PCMTD1 | c.940G>T p.E314* | Nonsense Mutation (SNP) | VAF 25/180 reads (14%) | catalogued as rs778884031, COSV62119638; called by muse, mutect2, varscan2
- PDCD11 | c.2228G>A p.G743D | Missense Mutation (SNP) | VAF 28/163 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1400436522, COSV104424978; called by muse, mutect2, varscan2
- PDXDC1 | c.11C>T p.S4F | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0); catalogued as rs1377505218; called by muse, mutect2
- PGM5 | c.1466T>A p.V489E | Missense Mutation (SNP) | VAF 30/164 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.851); catalogued as COSV67167688; called by muse, varscan2
- PIBF1 | c.956A>T p.D319V | Missense Mutation (SNP) | VAF 13/104 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1482385912; called by muse, varscan2
- PLAG1 | c.169A>T p.T57S | Missense Mutation (SNP) | VAF 25/123 reads (20%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.992); catalogued as COSV57612777; called by muse, mutect2, varscan2
- POM121L12 | c.725C>A p.P242H | Missense Mutation (SNP) | VAF 97/266 reads (36%) | SIFT tolerated (0.52); PolyPhen possibly damaging (0.605); catalogued as COSV68692550; called by muse, mutect2, varscan2
- POU3F4 | c.1031C>A p.P344Q | Missense Mutation (SNP) | VAF 33/133 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as COSV64541217; called by muse, mutect2, varscan2
- PPP1R17 | c.160C>A p.L54M | Missense Mutation (SNP) | VAF 18/178 reads (10%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.244); catalogued as rs779073308, COSV100566375; called by muse, mutect2
- PPP1R3A | c.3181G>A p.A1061T | Missense Mutation (SNP) | VAF 11/336 reads (3%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as rs1200768724; called by muse, mutect2
- PRAG1 | c.1175G>T p.G392V | Missense Mutation (SNP) | VAF 24/110 reads (22%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.905); catalogued as rs777670597, COSV58157548; called by muse, mutect2, varscan2
- PTPRT | c.3358C>G p.R1120G | Missense Mutation (SNP) | VAF 27/156 reads (17%) | SIFT tolerated (0.25); PolyPhen probably damaging (1); catalogued as COSV61957926; called by muse, mutect2, varscan2
- RALGDS | c.1421G>A p.R474Q | Missense Mutation (SNP) | VAF 46/346 reads (13%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as rs768088973; called by muse, mutect2, varscan2
- RASA3 | c.495C>A p.D165E | Missense Mutation (SNP) | VAF 17/255 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs766589668; called by muse, mutect2
- RBMX | c.142T>C p.S48P | Missense Mutation (SNP) | VAF 103/188 reads (55%) | SIFT deleterious (0); PolyPhen benign (0.125); catalogued as COSV57806828; called by muse, mutect2, varscan2
- RET | c.2825G>T p.W942L | Missense Mutation (SNP) | VAF 26/936 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM951129, COSV100393687; called by muse, mutect2
- RXRG | c.1224G>T p.K408N | Missense Mutation (SNP) | VAF 59/182 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.071); catalogued as COSV63231507; called by muse, mutect2, varscan2
- SALL1 | c.137G>T p.G46V | Missense Mutation (SNP) | VAF 28/265 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.64); catalogued as COSV51758694; called by muse, mutect2, varscan2
- SF3A3 | c.559G>C p.E187Q | Missense Mutation (SNP) | VAF 7/77 reads (9%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.979); catalogued as COSV65956721; called by muse, mutect2
- SH2D4B | c.358G>T p.E120* | Nonsense Mutation (SNP) | VAF 67/205 reads (33%) | catalogued as COSV57902810; called by muse, mutect2, varscan2
- SI | c.4984-1G>T p.X1662_splice | Splice Site (SNP) | VAF 22/306 reads (7%) | catalogued as COSV52284659; called by muse, mutect2
- SIGLEC5 | c.1460C>A p.T487N | Missense Mutation (SNP) | VAF 60/212 reads (28%) | SIFT tolerated (0.05); PolyPhen benign (0.017); catalogued as COSV99707126; called by muse, mutect2, varscan2
- SLC10A3 | c.296C>T p.T99M | Missense Mutation (SNP) | VAF 88/140 reads (63%) | SIFT tolerated (0.05); PolyPhen benign (0.017); catalogued as rs374139250; called by muse, mutect2, varscan2
- SLC12A2 | c.2894C>A p.S965Y | Missense Mutation (SNP) | VAF 21/162 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.186); catalogued as rs529490835; called by muse, mutect2, varscan2
- SLC16A8 | c.1013C>A p.A338E | Missense Mutation (SNP) | VAF 56/336 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.811); catalogued as rs769665559; called by muse, mutect2, varscan2
- SLC35F4 | c.1041G>T p.K347N (on ENST00000339762 / NM_001352015.2; = p.K311N on NM_001206920.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/113 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100333862; called by muse, mutect2, varscan2
- SLITRK5 | c.1294G>A p.A432T | Missense Mutation (SNP) | VAF 15/240 reads (6%) | SIFT tolerated (0.38); PolyPhen benign (0.044); catalogued as rs1474753086, COSV61522646; called by muse, mutect2
- SORCS1 | c.2432C>T p.A811V | Missense Mutation (SNP) | VAF 31/181 reads (17%) | SIFT tolerated (0.46); PolyPhen probably damaging (0.914); catalogued as rs150967356, COSV53884334; called by muse, mutect2, varscan2
- SOX30 | c.431C>A p.P144H | Missense Mutation (SNP) | VAF 70/432 reads (16%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0); catalogued as rs1383930128; called by muse, mutect2, varscan2
- SP100 | c.2086G>T p.D696Y | Missense Mutation (SNP) | VAF 21/204 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV50974740; called by muse, mutect2, varscan2
- SPEF2 | c.3705G>T p.M1235I | Missense Mutation (SNP) | VAF 49/223 reads (22%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV61554868; called by muse, mutect2, varscan2
- SPEF2 | c.3706G>T p.D1236Y | Missense Mutation (SNP) | VAF 49/224 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV61554876; called by muse, mutect2, varscan2
- SPOCD1 | c.337G>C p.A113P | Missense Mutation (SNP) | VAF 50/309 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.021); catalogued as rs958448667; called by muse, mutect2, varscan2
- SPOPL | c.388G>A p.D130N | Missense Mutation (SNP) | VAF 38/210 reads (18%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); catalogued as COSV54512499, COSV54512829; called by muse, mutect2, varscan2
- SVEP1 | c.9086G>C p.R3029P | Missense Mutation (SNP) | VAF 30/317 reads (9%) | SIFT tolerated (0.12); PolyPhen benign (0.18); catalogued as rs754622811, COSV52842582; called by muse, mutect2
- SYNE2 | c.1582G>C p.E528Q | Missense Mutation (SNP) | VAF 23/203 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.914); catalogued as COSV100647669, COSV59963609; called by muse, mutect2, varscan2
- TCERG1L | c.1259G>T p.R420L | Missense Mutation (SNP) | VAF 41/208 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.366); catalogued as COSV64048655; called by muse, mutect2, varscan2
- TEC | c.1852A>G p.T618A | Missense Mutation (SNP) | VAF 41/230 reads (18%) | SIFT tolerated (0.81); PolyPhen benign (0); catalogued as rs375268361; called by muse, mutect2, varscan2
- TECTA | c.4430G>A p.R1477H | Missense Mutation (SNP) | VAF 24/453 reads (5%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as rs527976707, COSV50747623; called by muse, mutect2
- TENM2 | c.6991C>T p.R2331C (on ENST00000518659 / NM_001122679.2; = p.R2092C on NM_001080428.3) | Missense Mutation (SNP) | VAF 20/416 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs369038425, COSV101318567; called by muse, mutect2
- TMEM204 | c.625C>A p.L209M | Missense Mutation (SNP) | VAF 68/292 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV99560031; called by muse, mutect2, varscan2
- TPTE2 | c.1199G>A p.R400K (on ENST00000400230 / NM_199254.2; = p.R323K on NM_130785.3) | Missense Mutation (SNP) | VAF 18/201 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs753841906, COSV55028843, COSV99690664; called by muse, mutect2
- TRIP12 | c.926G>A p.R309H | Missense Mutation (SNP) | VAF 26/288 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs757346052, COSV52262477; called by muse, mutect2
- TRPM6 | c.5048G>A p.R1683K | Missense Mutation (SNP) | VAF 48/436 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.112); catalogued as rs1162070529; called by muse, mutect2, varscan2
- TTYH3 | c.103G>T p.E35* | Nonsense Mutation (SNP) | VAF 83/310 reads (27%) | catalogued as COSV51858671; called by muse, mutect2, varscan2
- TXK | c.838G>T p.G280C | Missense Mutation (SNP) | VAF 39/268 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs746179718; called by muse, mutect2, varscan2
- UBR3 | c.4283A>G p.N1428S | Missense Mutation (SNP) | VAF 47/196 reads (24%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as rs1284735195, COSV55862941; called by muse, mutect2, varscan2
- UGT2B28 | c.871G>T p.E291* | Nonsense Mutation (SNP) | VAF 29/293 reads (10%) | catalogued as COSV59431098; called by muse, varscan2
- USH2A | c.8725G>T p.G2909C | Missense Mutation (SNP) | VAF 97/370 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs758347918, COSV100229215, COSV56410669; called by muse, mutect2, varscan2
- USH2A | c.8023C>A p.L2675I | Missense Mutation (SNP) | VAF 34/342 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.271); catalogued as COSV56336357, COSV56436976; called by muse, mutect2, varscan2
- WNK2 | c.1870G>A p.V624M | Missense Mutation (SNP) | VAF 12/88 reads (14%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as rs751183257, COSV52958263; called by muse, mutect2, varscan2
- WNK3 | c.556G>T p.A186S | Missense Mutation (SNP) | VAF 9/172 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.444); catalogued as COSV63615991; called by muse, mutect2
- ZEB2 | c.839G>T p.R280L | Missense Mutation (SNP) | VAF 56/441 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV57964996; called by muse, mutect2, varscan2
- ZNF496 | c.651G>T p.P217= | Splice Region (SNP) | VAF 16/171 reads (9%) | catalogued as COSV99666432; called by muse, mutect2
- ZNF682 | c.29C>T p.T10I | Missense Mutation (SNP) | VAF 12/134 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.034); catalogued as rs372727727; called by muse, mutect2
- ZNF714 | c.1019C>T p.P340L | Missense Mutation (SNP) | VAF 61/281 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.411); catalogued as rs776488209; called by muse, mutect2, varscan2
- ZNF764 | c.238G>A p.E80K | Missense Mutation (SNP) | VAF 44/421 reads (10%) | SIFT tolerated (0.84); PolyPhen benign (0.039); catalogued as rs750055611; called by muse, mutect2, varscan2
- ACACB | c.3188G>C p.R1063T | Missense Mutation (SNP) | VAF 198/372 reads (53%) | SIFT tolerated (0.11); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- ACSM2B | c.1039G>T p.E347* | Nonsense Mutation (SNP) | VAF 25/354 reads (7%) | called by muse, mutect2
- ACTN3 | c.2210C>A p.S737Y | Missense Mutation (SNP) | VAF 49/259 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.861); called by muse, mutect2, varscan2
- ADAMTS14 | c.2134C>T p.H712Y | Missense Mutation (SNP) | VAF 40/173 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.358); called by muse, mutect2, varscan2
- ADGRE2 | c.2350C>A p.Q784K | Missense Mutation (SNP) | VAF 56/154 reads (36%) | SIFT tolerated (0.87); PolyPhen possibly damaging (0.872); called by muse, mutect2, varscan2
- AL121899.2 | c.629C>A p.S210* | Nonsense Mutation (SNP) | VAF 77/256 reads (30%) | called by muse, mutect2, varscan2
- ALG13 | c.3383C>T p.P1128L | Missense Mutation (SNP) | VAF 22/115 reads (19%) | SIFT tolerated (0.05); PolyPhen benign (0.039); called by muse, varscan2
- AMH | c.898G>T p.A300S | Missense Mutation (SNP) | VAF 89/388 reads (23%) | SIFT tolerated (0.24); PolyPhen benign (0.198); called by muse, mutect2, varscan2
- ANKRD18A | c.1711G>T p.E571* | Nonsense Mutation (SNP) | VAF 44/127 reads (35%) | called by muse, mutect2, varscan2
- ANKRD33B | c.784_799del p.E262Lfs*25 | Frame Shift Del (DEL) | VAF 123/639 reads (19%) | called by mutect2, pindel, varscan2
- APBA1 | c.1369G>T p.D457Y | Missense Mutation (SNP) | VAF 25/179 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- APBB1IP | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 29/207 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- APEX1 | c.371A>G p.D124G | Missense Mutation (SNP) | VAF 56/225 reads (25%) | SIFT tolerated (0.14); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- APOB | c.7003A>T p.N2335Y | Missense Mutation (SNP) | VAF 16/252 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.851); called by muse, mutect2
- ARHGAP6 | c.548C>A p.P183H | Missense Mutation (SNP) | VAF 28/82 reads (34%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.674); called by muse, mutect2, varscan2
- ASNSD1 | c.907A>T p.R303W | Missense Mutation (SNP) | VAF 9/151 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); called by muse, mutect2
- ASPN | c.1066T>C p.Y356H | Missense Mutation (SNP) | VAF 26/222 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.707); called by muse, mutect2, varscan2
- ATCAY | c.768G>A p.M256I | Missense Mutation (SNP) | VAF 13/228 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.688); called by muse, mutect2
- AZGP1 | c.503G>T p.W168L | Missense Mutation (SNP) | VAF 56/163 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- BARD1 | c.714G>T p.K238N | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.691); called by muse, mutect2, varscan2
- BCL2L11 | c.548T>G p.I183S (on ENST00000393256 / NM_138621.5; = p.I123S on NM_006538.5) | Missense Mutation (SNP) | VAF 29/399 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.063); called by muse, mutect2
- BEX3 | c.88C>A p.H30N | Missense Mutation (SNP) | VAF 8/215 reads (4%) | SIFT tolerated (0.1); PolyPhen benign (0.001); called by muse, mutect2
- BPIFB3 | c.650T>A p.L217Q | Missense Mutation (SNP) | VAF 26/257 reads (10%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.694); called by muse, mutect2, varscan2
- BRS3 | c.338G>T p.W113L | Missense Mutation (SNP) | VAF 103/195 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- C21orf62 | c.566T>A p.V189D | Missense Mutation (SNP) | VAF 28/260 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.681); called by muse, mutect2
- CALHM1 | c.938T>G p.L313R | Missense Mutation (SNP) | VAF 49/418 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CAMK2A | c.1052T>A p.I351K (on ENST00000348628 / NM_171825.2; = p.I362K on NM_015981.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 34/271 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.944); called by muse, mutect2, varscan2
- CASR | c.1471T>A p.C491S (on ENST00000490131; = p.C568S on NM_000388.4) | Missense Mutation (SNP) | VAF 20/290 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2
- CCDC115 | c.351G>T p.E117D | Missense Mutation (SNP) | VAF 35/208 reads (17%) | SIFT tolerated (0.6); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- CCDC168 | c.4546C>T p.H1516Y | Missense Mutation (SNP) | VAF 44/155 reads (28%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.737); called by muse, mutect2, varscan2
- CDC14C | c.537C>A p.C179* (on ENST00000428251; = p.C72* on NM_152627.3) | Nonsense Mutation (SNP) | VAF 27/240 reads (11%) | called by muse, mutect2, varscan2
- CDHR5 | c.564C>G p.D188E | Missense Mutation (SNP) | VAF 77/202 reads (38%) | SIFT tolerated (0.1); PolyPhen benign (0.187); called by muse, mutect2, varscan2
- CILP | c.2963G>T p.R988L | Missense Mutation (SNP) | VAF 41/128 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CLCA4 | c.951G>T p.M317I | Missense Mutation (SNP) | VAF 12/78 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, varscan2
- CLEC4F | c.46T>C p.S16P | Missense Mutation (SNP) | VAF 18/184 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.797); called by muse, varscan2
- COL11A2 | c.2211G>T p.E737D (on ENST00000341947 / NM_080680.3; = p.E630D on NM_080679.2) | Missense Mutation (SNP) | VAF 58/667 reads (9%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.874); called by muse, mutect2
- COL4A1 | c.190G>A p.G64R | Missense Mutation (SNP) | VAF 52/417 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- COL6A2 | c.928-1G>T p.X310_splice | Splice Site (SNP) | VAF 170/689 reads (25%) | called by muse, mutect2, varscan2
- CSTL1 | c.353T>A p.I118K | Missense Mutation (SNP) | VAF 24/160 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.525); called by muse, mutect2, varscan2
- CYP7A1 | c.1105G>T p.D369Y | Missense Mutation (SNP) | VAF 72/398 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- DECR2 | c.103G>C p.G35R | Missense Mutation (SNP) | VAF 11/202 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- DGKI | c.2585C>A p.P862Q | Missense Mutation (SNP) | VAF 62/252 reads (25%) | SIFT tolerated (0.72); PolyPhen benign (0.003); called by muse, varscan2
- DHRS2 | c.580G>T p.G194C | Missense Mutation (SNP) | VAF 46/304 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DLC1 | c.3890A>G p.Y1297C (on ENST00000276297 / NM_001348081.2; = p.Y860C on NM_006094.5) | Missense Mutation (SNP) | VAF 24/120 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.068); called by muse, mutect2, varscan2
- DNAH7 | c.1411G>T p.A471S | Missense Mutation (SNP) | VAF 52/164 reads (32%) | SIFT tolerated (0.72); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- DNM3 | c.254A>G p.H85R | Missense Mutation (SNP) | VAF 18/84 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- DOCK6 | c.1234G>A p.D412N | Missense Mutation (SNP) | VAF 39/183 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.434); called by muse, mutect2, varscan2
- ENPEP | c.1130A>T p.K377M | Missense Mutation (SNP) | VAF 24/275 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.153); called by muse, mutect2
- EP400 | c.1525C>A p.L509I | Missense Mutation (SNP) | VAF 46/209 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- EPG5 | c.6800G>T p.S2267I | Missense Mutation (SNP) | VAF 32/272 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.89); called by muse, mutect2, varscan2
- ERCC6 | c.1374A>T p.E458D | Missense Mutation (SNP) | VAF 38/275 reads (14%) | SIFT tolerated (0.31); PolyPhen benign (0.212); called by muse, mutect2, varscan2
- ESYT2 | c.1262G>T p.G421V (on ENST00000613624; = p.G345V on NM_020728.3) | Missense Mutation (SNP) | VAF 31/146 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- EVC2 | c.1471-1G>T p.X491_splice | Splice Site (SNP) | VAF 16/109 reads (15%) | called by muse, mutect2, varscan2
- EYS | c.4966G>T p.D1656Y | Missense Mutation (SNP) | VAF 31/150 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- EYS | c.551C>G p.S184C | Missense Mutation (SNP) | VAF 17/95 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FAM114A2 | c.1514A>G p.H505R | Missense Mutation (SNP) | VAF 26/132 reads (20%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); called by muse, mutect2
- FAM200A | c.568G>T p.E190* | Nonsense Mutation (SNP) | VAF 28/175 reads (16%) | called by muse, mutect2, varscan2
- FAT1 | c.3877G>C p.D1293H | Missense Mutation (SNP) | VAF 37/271 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.633); called by muse, mutect2, varscan2
- FLG | c.4518G>T p.E1506D | Missense Mutation (SNP) | VAF 184/810 reads (23%) | SIFT tolerated (0.42); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- FOXL1 | c.857A>T p.K286M | Missense Mutation (SNP) | VAF 43/309 reads (14%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.907); called by muse, mutect2, varscan2
- FOXO4 | c.239C>T p.P80L | Missense Mutation (SNP) | VAF 62/125 reads (50%) | SIFT tolerated (0.14); PolyPhen benign (0.014); called by muse, varscan2
- FOXQ1 | c.40G>T p.D14Y | Missense Mutation (SNP) | VAF 45/86 reads (52%) | SIFT deleterious (0.01); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- GABRG1 | c.1183T>A p.S395T | Missense Mutation (SNP) | VAF 12/290 reads (4%) | SIFT tolerated (0.67); PolyPhen benign (0); called by muse, mutect2
- GAL3ST1 | c.717C>G p.I239M | Missense Mutation (SNP) | VAF 84/443 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- GALNT9 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 38/164 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.885); called by muse, varscan2
- GCNT3 | c.221C>T p.T74I | Missense Mutation (SNP) | VAF 50/137 reads (36%) | SIFT tolerated (0.89); PolyPhen benign (0); called by muse, mutect2, varscan2
- GK2 | c.1119G>T p.E373D | Missense Mutation (SNP) | VAF 40/231 reads (17%) | SIFT tolerated (0.17); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- GNB3 | c.106G>T p.G36C | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.571); called by muse, mutect2, varscan2
- GPHN | c.67A>C p.S23R | Missense Mutation (SNP) | VAF 58/328 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- GPI | c.1187A>G p.H396R | Missense Mutation (SNP) | VAF 28/189 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GPR151 | c.94T>A p.S32T | Missense Mutation (SNP) | VAF 45/325 reads (14%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.643); called by muse, mutect2, varscan2
- GRM5 | c.909C>A p.G303= | Splice Region (SNP) | VAF 55/162 reads (34%) | called by muse, mutect2, varscan2
- GRM8 | c.2089del p.V697* | Frame Shift Del (DEL) | VAF 14/91 reads (15%) | called by mutect2, pindel, varscan2
- GUCY1A2 | c.2044C>A p.L682I | Missense Mutation (SNP) | VAF 53/334 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- HECW1 | c.167G>T p.G56V | Missense Mutation (SNP) | VAF 63/430 reads (15%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.299); called by muse, mutect2, varscan2
- HGF | c.139A>G p.K47E | Missense Mutation (SNP) | VAF 48/315 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- HHIPL2 | c.517G>C p.D173H | Missense Mutation (SNP) | VAF 159/663 reads (24%) | SIFT tolerated (0.18); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- HK3 | c.247C>A p.P83T | Missense Mutation (SNP) | VAF 59/159 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- HOXA10 | c.420G>T p.Q140H | Missense Mutation (SNP) | VAF 346/576 reads (60%) | SIFT tolerated (0.59); PolyPhen benign (0.121); called by muse, mutect2, varscan2
- HRNR | c.2399G>T p.C800F | Missense Mutation (SNP) | VAF 14/418 reads (3%) | SIFT tolerated (0.14); PolyPhen benign (0.021); called by muse, mutect2
- IFIT1 | c.991T>C p.S331P | Missense Mutation (SNP) | VAF 36/262 reads (14%) | SIFT tolerated (0.24); PolyPhen benign (0.091); called by muse, mutect2, varscan2
- IFT88 | c.2234G>T p.G745V (on ENST00000319980 / NM_001318493.2; = p.G736V on NM_006531.5 and 9 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/170 reads (8%) | SIFT tolerated (0.35); PolyPhen benign (0.051); called by muse, mutect2
- IGKV1-5 | c.197C>A p.P66H | Missense Mutation (SNP) | VAF 75/790 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2
- IRF4 | c.539A>T p.D180V | Missense Mutation (SNP) | VAF 28/575 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.474); called by muse, mutect2
- ISG20 | c.532G>T p.A178S | Missense Mutation (SNP) | VAF 45/120 reads (38%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ISL1 | c.247A>G p.S83G | Missense Mutation (SNP) | VAF 56/493 reads (11%) | SIFT tolerated (0.57); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- KCNH7 | c.3581C>A p.P1194Q | Missense Mutation (SNP) | VAF 14/83 reads (17%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- KDM4C | c.430G>A p.D144N | Missense Mutation (SNP) | VAF 29/115 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- KIAA1549 | c.4037A>T p.Q1346L | Missense Mutation (SNP) | VAF 20/88 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2
- KIF14 | c.4840G>T p.D1614Y | Missense Mutation (SNP) | VAF 60/298 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- KIF2B | c.472G>T p.E158* | Nonsense Mutation (SNP) | VAF 57/191 reads (30%) | called by muse, mutect2, varscan2
- KIR2DL1 | c.917A>G p.N306S | Missense Mutation (SNP) | VAF 87/602 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- KPNA3 | c.958C>T p.Q320* | Nonsense Mutation (SNP) | VAF 24/156 reads (15%) | called by muse, mutect2, varscan2
- KRT33A | c.823C>A p.L275M | Missense Mutation (SNP) | VAF 37/401 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- LAMA5 | c.1531A>T p.R511W | Missense Mutation (SNP) | VAF 74/268 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- LCE6A | c.73C>A p.P25T | Missense Mutation (SNP) | VAF 96/216 reads (44%) | SIFT tolerated (0.28); PolyPhen benign (0.262); called by muse, varscan2
- LILRB2 | c.658G>T p.G220C | Missense Mutation (SNP) | VAF 16/110 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2
- LMAN2 | c.466G>T p.G156C | Missense Mutation (SNP) | VAF 69/460 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.291); called by muse, mutect2, varscan2
- LRRC43 | c.834C>A p.C278* | Nonsense Mutation (SNP) | VAF 14/497 reads (3%) | called by muse, mutect2
- LRRC8C | c.1224A>C p.E408D | Missense Mutation (SNP) | VAF 33/231 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- LRRD1 | c.110C>A p.S37* | Nonsense Mutation (SNP) | VAF 9/108 reads (8%) | called by muse, mutect2
- MADCAM1 | c.466C>G p.Q156E | Missense Mutation (SNP) | VAF 3/22 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- MAPK8IP2 | c.1522G>C p.A508P | Missense Mutation (SNP) | VAF 33/282 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.9); called by muse, mutect2, varscan2
- MGA | c.1730T>A p.L577H | Missense Mutation (SNP) | VAF 31/169 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.41); called by muse, mutect2, varscan2
- MIS12 | c.463A>T p.T155S | Missense Mutation (SNP) | VAF 45/124 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.432); called by muse, mutect2, varscan2
- MNDA | c.542C>A p.S181* | Nonsense Mutation (SNP) | VAF 19/79 reads (24%) | called by muse, mutect2, varscan2
- MPST | c.572G>T p.G191V (on ENST00000341116 / NM_001369904.2; = p.G211V on NM_021126.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 49/263 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MROH2B | c.4078G>A p.E1360K | Missense Mutation (SNP) | VAF 57/225 reads (25%) | SIFT tolerated (0.23); PolyPhen benign (0.095); called by muse, mutect2, varscan2
- MTMR12 | c.359-1G>A p.X120_splice | Splice Site (SNP) | VAF 7/75 reads (9%) | called by muse, mutect2
- MTNR1A | c.508T>A p.Y170N | Missense Mutation (SNP) | VAF 8/177 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- MYH7 | c.1213A>T p.K405* | Nonsense Mutation (SNP) | VAF 30/462 reads (6%) | called by muse, mutect2
- N4BP2L2 | c.2269G>T p.D757Y (on ENST00000674422; = p.D328Y on NM_033111.4) | Missense Mutation (SNP) | VAF 21/71 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.36); called by muse, mutect2, varscan2
- NLRP10 | c.1135A>G p.R379G | Missense Mutation (SNP) | VAF 34/219 reads (16%) | SIFT tolerated (0.24); PolyPhen benign (0.101); called by muse, mutect2, varscan2
- NLRP13 | c.2790-2A>T p.X930_splice | Splice Site (SNP) | VAF 5/68 reads (7%) | called by muse, mutect2
- NLRP7 | c.2623T>C p.C875R (on ENST00000340844 / NM_206828.3; = p.C847R on NM_139176.3) | Missense Mutation (SNP) | VAF 74/451 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); called by muse, mutect2, varscan2
- NRXN3 | c.1180G>A p.G394S (on ENST00000335750 / NM_001330195.2; = p.G21S on NM_004796.6) | Missense Mutation (SNP) | VAF 46/192 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- NTNG1 | c.653G>C p.S218T | Missense Mutation (SNP) | VAF 8/182 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.229); called by muse, mutect2
- OBSCN | c.8597T>C p.I2866T | Missense Mutation (SNP) | VAF 90/319 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- OBSCN | c.9775G>C p.G3259R | Missense Mutation (SNP) | VAF 40/245 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.792); called by muse, mutect2, varscan2
- OR2AJ1 | c.286G>C p.G96R | Missense Mutation (SNP) | VAF 54/280 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- OR2AJ1 | c.287G>T p.G96V | Missense Mutation (SNP) | VAF 56/284 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); called by muse, mutect2, varscan2
- OR52W1 | c.814C>T p.H272Y | Missense Mutation (SNP) | VAF 140/402 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- OTOF | c.3158C>T p.A1053V (on ENST00000272371 / NM_194248.3; = p.A306V on NM_004802.4) | Missense Mutation (SNP) | VAF 15/487 reads (3%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); called by muse, mutect2
- OTOG | c.1437C>A p.H479Q | Missense Mutation (SNP) | VAF 85/280 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.225); called by muse, mutect2, varscan2
- PARP14 | c.1504G>T p.D502Y | Missense Mutation (SNP) | VAF 32/155 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- PAX1 | c.1408G>C p.D470H | Missense Mutation (SNP) | VAF 36/372 reads (10%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.091); called by muse, mutect2
- PCDHA4 | c.1621G>C p.G541R | Missense Mutation (SNP) | VAF 313/908 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PCDHGA1 | c.917C>T p.P306L | Missense Mutation (SNP) | VAF 13/151 reads (9%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.021); called by muse, mutect2
- PCDHGA1 | c.1865A>T p.H622L | Missense Mutation (SNP) | VAF 18/530 reads (3%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.862); called by muse, mutect2
- PCDHGA3 | c.238C>A p.Q80K | Missense Mutation (SNP) | VAF 44/283 reads (16%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PDE4B | c.94A>T p.S32C | Missense Mutation (SNP) | VAF 34/198 reads (17%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.439); called by muse, mutect2, varscan2
- PIN4 | c.358C>G p.Q120E (on ENST00000664196; = p.Q95E on NM_006223.4) | Missense Mutation (SNP) | VAF 29/100 reads (29%) | SIFT tolerated (0.33); PolyPhen benign (0.207); called by muse, mutect2, varscan2
- PKN3 | c.1522A>T p.T508S | Missense Mutation (SNP) | VAF 40/184 reads (22%) | SIFT tolerated (0.79); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- PLA2R1 | c.2636A>T p.E879V | Missense Mutation (SNP) | VAF 32/152 reads (21%) | SIFT tolerated (0.27); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- POM121L2 | c.1588G>T p.A530S | Missense Mutation (SNP) | VAF 44/328 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.105); called by muse, mutect2, varscan2
- POU4F3 | c.637G>A p.A213T | Missense Mutation (SNP) | VAF 80/532 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- PROB1 | c.2668C>G p.R890G | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); called by muse, mutect2
- PRRT4 | c.936C>A p.N312K | Missense Mutation (SNP) | VAF 41/233 reads (18%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PSENEN | c.167-8C>A | Splice Region (SNP) | VAF 24/596 reads (4%) | called by muse, mutect2
- PSMB9 | c.571G>T p.G191C | Missense Mutation (SNP) | VAF 19/118 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PTGFRN | c.1781G>T p.G594V | Missense Mutation (SNP) | VAF 48/276 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.334); called by mutect2, varscan2
- PTPRM | c.259C>A p.P87T | Missense Mutation (SNP) | VAF 14/236 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2
- PURA | c.535G>A p.G179S | Missense Mutation (SNP) | VAF 54/273 reads (20%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.733); called by muse, mutect2, varscan2
- RNASE1 | c.396A>T p.R132S | Missense Mutation (SNP) | VAF 35/311 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- RNF152 | c.175A>C p.K59Q | Missense Mutation (SNP) | VAF 73/251 reads (29%) | SIFT tolerated (0.34); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- RNF182 | c.419G>T p.S140I | Missense Mutation (SNP) | VAF 19/290 reads (7%) | SIFT deleterious (0.05); PolyPhen benign (0.278); called by muse, mutect2
- ROR2 | c.2526C>G p.I842M | Missense Mutation (SNP) | VAF 32/186 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- RTL1 | c.2488G>T p.A830S | Missense Mutation (SNP) | VAF 22/276 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.195); called by muse, mutect2
- SDK2 | c.722C>G p.A241G | Missense Mutation (SNP) | VAF 56/426 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- SEMA3C | c.616A>G p.N206D | Missense Mutation (SNP) | VAF 38/197 reads (19%) | SIFT tolerated (0.59); PolyPhen possibly damaging (0.796); called by muse, mutect2, varscan2
- SEPTIN14 | c.1201G>T p.G401* | Nonsense Mutation (SNP) | VAF 100/542 reads (18%) | called by muse, mutect2, varscan2
- SIGLEC10 | c.1105C>A p.P369T | Missense Mutation (SNP) | VAF 23/64 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.364); called by muse, mutect2, varscan2
- SIGLECL1 | c.88C>A p.H30N | Missense Mutation (SNP) | VAF 34/234 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.677); called by muse, mutect2, varscan2
- SIGLECL1 | c.89A>T p.H30L | Missense Mutation (SNP) | VAF 33/240 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.602); called by muse, mutect2, varscan2
- SLAMF1 | c.162G>C p.K54N | Missense Mutation (SNP) | VAF 41/374 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.501); called by muse, mutect2, varscan2
- SLC14A2 | c.2571G>C p.L857F | Missense Mutation (SNP) | VAF 20/179 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- SLC3A1 | c.354G>T p.W118C | Missense Mutation (SNP) | VAF 20/531 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- SLC8A1 | c.1403C>A p.P468H | Missense Mutation (SNP) | VAF 11/122 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); called by muse, mutect2
- SLITRK5 | c.1295C>A p.A432D | Missense Mutation (SNP) | VAF 16/242 reads (7%) | SIFT tolerated (0.18); PolyPhen benign (0.359); called by muse, mutect2
- SMYD5 | c.770G>C p.G257A | Missense Mutation (SNP) | VAF 17/333 reads (5%) | SIFT tolerated (0.18); PolyPhen probably damaging (1); called by muse, mutect2
- STAC3 | c.551G>T p.G184V | Missense Mutation (SNP) | VAF 167/388 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SUGP1 | c.1484C>T p.T495I | Missense Mutation (SNP) | VAF 67/185 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.65); called by muse, mutect2, varscan2
- SUPT20HL1 | c.1723C>G p.P575A | Missense Mutation (SNP) | VAF 43/209 reads (21%) | SIFT tolerated (0.35); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- SYT13 | c.369del p.R124Gfs*54 | Frame Shift Del (DEL) | VAF 84/261 reads (32%) | called by mutect2, pindel, varscan2
- TBC1D9B | c.1940G>T p.R647I | Missense Mutation (SNP) | VAF 67/312 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- TDP1 | c.1110G>A p.W370* | Nonsense Mutation (SNP) | VAF 48/296 reads (16%) | called by muse, mutect2, varscan2
- TDRD5 | c.832-1G>C p.X278_splice | Splice Site (SNP) | VAF 12/148 reads (8%) | called by muse, mutect2
- TMC3 | c.1163C>A p.P388H | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- TMEM232 | c.1277-1G>T p.X426_splice | Splice Site (SNP) | VAF 25/186 reads (13%) | called by muse, mutect2, varscan2
- TMEM94 | c.1913-1G>T p.X638_splice | Splice Site (SNP) | VAF 14/130 reads (11%) | called by muse, mutect2, varscan2
- TMTC1 | c.545C>A p.S182* (on ENST00000539277 / NM_001193451.2; = p.S74* on NM_175861.3) | Nonsense Mutation (SNP) | VAF 46/295 reads (16%) | called by muse, mutect2, varscan2
- TNFRSF18 | c.190G>T p.E64* | Nonsense Mutation (SNP) | VAF 26/160 reads (16%) | called by muse, mutect2
- TNN | c.3403G>T p.D1135Y | Missense Mutation (SNP) | VAF 17/456 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2
- TOPAZ1 | c.698C>T p.P233L | Missense Mutation (SNP) | VAF 14/72 reads (19%) | SIFT tolerated (0.7); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- TRPC5 | c.2812A>C p.K938Q | Missense Mutation (SNP) | VAF 17/78 reads (22%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- TTN | c.28253A>C p.K9418T (on ENST00000591111; = p.K8491T on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/142 reads (11%) | PolyPhen probably damaging (0.997); called by muse, mutect2
- TUBA3E | c.1172T>A p.L391Q | Missense Mutation (SNP) | VAF 38/343 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- UHRF2 | c.224C>T p.P75L | Missense Mutation (SNP) | VAF 34/308 reads (11%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.464); called by muse, mutect2, varscan2
- UNC13D | c.2954+7G>T | Splice Region (SNP) | VAF 97/364 reads (27%) | called by muse, mutect2, varscan2
- USP18 | c.383A>G p.Q128R | Missense Mutation (SNP) | VAF 26/131 reads (20%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.627); called by muse, mutect2, varscan2
- USP6 | c.3908G>T p.R1303I | Missense Mutation (SNP) | VAF 22/198 reads (11%) | SIFT tolerated, low confidence (0.09); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- VAV3 | c.1336G>C p.D446H | Missense Mutation (SNP) | VAF 20/162 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- WIPF1 | c.1129G>A p.G377S | Missense Mutation (SNP) | VAF 47/493 reads (10%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.466); called by muse, mutect2
- XIRP2 | c.4067C>G p.T1356R (on ENST00000628543; = p.T1531R on NM_152381.6) | Missense Mutation (SNP) | VAF 39/139 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZFHX3 | c.472G>T p.G158W | Missense Mutation (SNP) | VAF 57/270 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- ZNF18 | c.1581_1582del p.S528Ffs*8 | Frame Shift Del (DEL) | VAF 12/69 reads (17%) | called by mutect2, pindel, varscan2
- ZNF234 | c.33G>T p.K11N | Missense Mutation (SNP) | VAF 95/316 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ZNF384 | c.832C>T p.H278Y | Missense Mutation (SNP) | VAF 22/296 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2
- ZNF479 | c.943C>A p.H315N | Missense Mutation (SNP) | VAF 15/348 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2
- ZNF552 | c.602G>T p.C201F | Missense Mutation (SNP) | VAF 51/250 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.612); called by muse, mutect2, varscan2
- ZNF716 | c.64G>T p.A22S | Missense Mutation (SNP) | VAF 30/295 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.848); called by muse, mutect2
- ZWINT | c.737C>A p.P246H | Missense Mutation (SNP) | VAF 30/231 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- ADAMTS20 | c.4887T>G p.L1629= | Silent (SNP) | VAF 10/280 reads (4%) | called by muse, mutect2
- ADGRB1 | c.768C>A p.G256= | Silent (SNP) | VAF 29/146 reads (20%) | catalogued as rs987598780; called by muse, mutect2, varscan2
- ADGRB3 | c.3552C>A p.I1184= | Silent (SNP) | VAF 18/98 reads (18%) | catalogued as COSV53259521; called by muse, mutect2
- ANKRD7 | c.354A>G p.P118= | Silent (SNP) | VAF 19/156 reads (12%) | catalogued as rs745478485; called by muse, mutect2, varscan2
- ASTN1 | c.717G>T p.L239= | Silent (SNP) | VAF 48/413 reads (12%) | called by muse, mutect2, varscan2
- ASXL3 | c.2922C>T p.I974= | Silent (SNP) | VAF 34/156 reads (22%) | catalogued as COSV52456558; called by muse, mutect2, varscan2
- BMP3 | c.123G>T p.T41= | Silent (SNP) | VAF 101/587 reads (17%) | catalogued as rs202167056; called by muse, mutect2, varscan2
- C6 | c.1782C>A p.P594= | Silent (SNP) | VAF 48/348 reads (14%) | catalogued as rs545271270, COSV99666748; called by muse, mutect2, varscan2
- C7orf31 | c.1176C>T p.N392= | Silent (SNP) | VAF 42/399 reads (11%) | catalogued as COSV52220700; called by muse, mutect2, varscan2
- CACNA1A | c.7002C>A p.A2334= | Silent (SNP) | VAF 15/287 reads (5%) | called by muse, mutect2
- CBFA2T3 | c.1770C>T p.H590= | Silent (SNP) | VAF 70/364 reads (19%) | catalogued as COSV99242048; called by muse, mutect2, varscan2
- CCDC168 | c.16476G>A p.Q5492= | Silent (SNP) | VAF 82/274 reads (30%) | called by muse, mutect2, varscan2
- CEBPE | c.664C>A p.R222= | Silent (SNP) | VAF 75/454 reads (17%) | catalogued as COSV52830088; called by muse, mutect2, varscan2
- CHRM2 | c.1173T>A p.A391= | Silent (SNP) | VAF 5/122 reads (4%) | called by muse, mutect2
- CRACD | c.1036C>A p.R346= | Silent (SNP) | VAF 8/32 reads (25%) | called by muse, mutect2, varscan2
- CTCFL | c.109A>C p.R37= | Silent (SNP) | VAF 45/360 reads (13%) | called by muse, mutect2, varscan2
- DCP2 | c.27C>T p.P9= | Silent (SNP) | VAF 17/132 reads (13%) | catalogued as rs769592289, COSV101203921; called by muse, varscan2
- DEF6 | c.861C>T p.N287= | Silent (SNP) | VAF 22/220 reads (10%) | called by muse, mutect2
- DIAPH3 | c.141C>T p.P47= | Silent (SNP) | VAF 31/96 reads (32%) | called by muse, mutect2, varscan2
- DLK1 | c.930G>T p.L310= | Silent (SNP) | VAF 58/210 reads (28%) | called by muse, mutect2, varscan2
- DLL3 | c.1680C>T p.S560= | Silent (SNP) | VAF 18/576 reads (3%) | called by muse, mutect2
- DOCK3 | c.993C>A p.L331= | Silent (SNP) | VAF 23/151 reads (15%) | called by muse, mutect2, varscan2
- DRD5 | c.711C>A p.P237= | Silent (SNP) | VAF 50/233 reads (21%) | catalogued as rs753915673; called by muse, mutect2, varscan2
- DSG4 | c.1290G>T p.G430= | Silent (SNP) | VAF 35/181 reads (19%) | called by muse, mutect2, varscan2
- DYRK1A | c.18G>A p.E6= | Silent (SNP) | VAF 9/40 reads (23%) | called by muse, mutect2, varscan2
- ERVV-2 | c.918A>T p.I306= | Silent (SNP) | VAF 30/154 reads (19%) | called by mutect2, varscan2
- FAM78B | c.628C>A p.R210= | Silent (SNP) | VAF 28/118 reads (24%) | called by muse, mutect2, varscan2
- FAM78B | c.627C>A p.A209= | Silent (SNP) | VAF 29/121 reads (24%) | called by muse, mutect2, varscan2
- FAT3 | c.11185C>T p.L3729= | Silent (SNP) | VAF 40/113 reads (35%) | catalogued as rs1335478039; called by muse, mutect2, varscan2
- FMN1 | c.4248G>T p.V1416= (on ENST00000616417 / NM_001277313.2; = p.V1193= on NM_001103184.4) | Silent (SNP) | VAF 52/272 reads (19%) | called by muse, mutect2, varscan2
- FOXO1 | c.1449G>T p.G483= | Silent (SNP) | VAF 19/242 reads (8%) | called by muse, mutect2
- FRMD1 | c.963G>C p.L321= | Silent (SNP) | VAF 80/503 reads (16%) | called by muse, mutect2, varscan2
- GLI2 | c.2208G>C p.T736= (on ENST00000361492 / NM_001374353.1; = p.T753= on NM_005270.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 30/122 reads (25%) | called by muse, mutect2, varscan2
- GLS2 | c.972C>T p.I324= | Silent (SNP) | VAF 181/426 reads (42%) | catalogued as rs559073025, COSV57665372; called by muse, mutect2, varscan2
- GRAMD1C | c.1830A>T p.A610= | Silent (SNP) | VAF 28/87 reads (32%) | called by muse, mutect2, varscan2
- H3-5 | c.375G>A p.Q125= | Silent (SNP) | VAF 110/259 reads (42%) | called by muse, mutect2, varscan2
- HBG2 | c.270T>C p.S90= | Silent (SNP) | VAF 38/1206 reads (3%) | called by muse, mutect2
- HOXA1 | c.897C>T p.T299= | Silent (SNP) | VAF 80/516 reads (16%) | catalogued as rs1413087993; called by muse, mutect2, varscan2
- IGSF1 | c.2049C>A p.L683= | Silent (SNP) | VAF 17/59 reads (29%) | catalogued as COSV100811753; called by muse, mutect2, varscan2
- ITGA8 | c.1317A>T p.G439= | Silent (SNP) | VAF 24/292 reads (8%) | called by muse, mutect2
- ITPRID1 | c.2337C>A p.L779= | Silent (SNP) | VAF 40/308 reads (13%) | called by muse, mutect2, varscan2
- KCNH4 | c.1401C>T p.H467= | Silent (SNP) | VAF 28/270 reads (10%) | catalogued as rs139967980; called by muse, varscan2
- KEL | c.303C>A p.T101= | Silent (SNP) | VAF 123/464 reads (27%) | catalogued as rs778069705, COSV62333058; called by muse, mutect2, varscan2
- KIR3DL1 | c.684C>T p.A228= | Silent (SNP) | VAF 55/363 reads (15%) | catalogued as COSV100428688; called by muse, mutect2, varscan2
- KLHL30 | c.1401T>A p.A467= | Silent (SNP) | VAF 81/385 reads (21%) | called by muse, mutect2, varscan2
- LRP1B | c.3510C>A p.G1170= | Silent (SNP) | VAF 25/170 reads (15%) | catalogued as COSV67257382; called by muse, mutect2, varscan2
- LRP2 | c.13362T>A p.L4454= | Silent (SNP) | VAF 65/622 reads (10%) | called by muse, mutect2, varscan2
- LYG2 | c.492C>A p.P164= | Silent (SNP) | VAF 38/348 reads (11%) | catalogued as COSV100283618; called by muse, mutect2, varscan2
- MACO1 | c.1797A>G p.Q599= | Silent (SNP) | VAF 46/154 reads (30%) | catalogued as rs1389080412; called by muse, mutect2, varscan2
- MGAM2 | c.2304C>T p.Y768= | Silent (SNP) | VAF 18/96 reads (19%) | called by muse, mutect2, varscan2
- MIA3 | c.5541A>T p.S1847= | Silent (SNP) | VAF 98/373 reads (26%) | catalogued as COSV100388167; called by muse, mutect2, varscan2
- MRO | c.216G>A p.L72= | Silent (SNP) | VAF 57/213 reads (27%) | called by muse, mutect2, varscan2
- MTO1 | c.1194C>T p.L398= | Silent (SNP) | VAF 41/170 reads (24%) | catalogued as rs759654432; called by muse, varscan2
- MUC5B | c.13128C>A p.T4376= | Silent (SNP) | VAF 180/577 reads (31%) | catalogued as COSV101500222; called by muse, mutect2, varscan2
- MUC5B | c.13794C>G p.T4598= | Silent (SNP) | VAF 67/482 reads (14%) | called by muse, mutect2, varscan2
- MYH7 | c.1212G>T p.V404= | Silent (SNP) | VAF 30/459 reads (7%) | catalogued as CD1010368; called by muse, mutect2
- MYO18B | c.792G>A p.Q264= | Silent (SNP) | VAF 5/27 reads (19%) | catalogued as COSV59137980; called by muse, mutect2
- NBPF9 | c.348G>T p.G116= | Silent (SNP) | VAF 96/585 reads (16%) | called by muse, mutect2, varscan2
- NEXMIF | c.2769C>T p.S923= | Silent (SNP) | VAF 43/145 reads (30%) | called by muse, varscan2
- NLGN4X | c.975G>A p.E325= | Silent (SNP) | VAF 105/395 reads (27%) | called by muse, mutect2, varscan2
- NPAP1 | c.2004G>T p.L668= | Silent (SNP) | VAF 51/140 reads (36%) | called by muse, mutect2, varscan2
- NRXN3 | c.1179T>A p.P393= (on ENST00000335750 / NM_001330195.2; = p.P20= on NM_004796.6) | Silent (SNP) | VAF 45/191 reads (24%) | called by muse, mutect2, varscan2
- NUAK2 | c.402G>C p.R134= | Silent (SNP) | VAF 58/269 reads (22%) | called by muse, mutect2, varscan2
- OR2W3 | c.426G>A p.R142= | Silent (SNP) | VAF 35/291 reads (12%) | catalogued as COSV64456668; called by muse, mutect2, varscan2
- OR4K5 | c.87T>C p.C29= | Silent (SNP) | VAF 50/379 reads (13%) | called by muse, mutect2, varscan2
- OR8H3 | c.828G>T p.V276= | Silent (SNP) | VAF 32/130 reads (25%) | catalogued as rs757219655; called by muse, mutect2, varscan2
- PCARE | c.1353G>A p.G451= | Silent (SNP) | VAF 60/276 reads (22%) | catalogued as rs767747198, COSV100527259, COSV100527522; called by muse, mutect2, varscan2
- PCDHA12 | c.1860C>T p.I620= | Silent (SNP) | VAF 165/519 reads (32%) | called by muse, mutect2, varscan2
- PCDHGB2 | c.141A>T p.V47= | Silent (SNP) | VAF 63/386 reads (16%) | called by muse, mutect2, varscan2
- PDE8A | c.1773C>T p.I591= | Silent (SNP) | VAF 11/143 reads (8%) | catalogued as rs772977823; called by muse, mutect2
- PHF3 | c.1947C>T p.H649= | Silent (SNP) | VAF 34/261 reads (13%) | called by muse, mutect2, varscan2
- PKD1L2 | c.1515G>T p.G505= | Silent (SNP) | VAF 28/114 reads (25%) | called by muse, mutect2
- PLXNA2 | c.1905A>G p.L635= | Silent (SNP) | VAF 79/309 reads (26%) | called by muse, mutect2, varscan2
- PRELID2 | c.45C>T p.F15= | Silent (SNP) | VAF 10/236 reads (4%) | called by muse, mutect2
- PRF1 | c.522G>T p.V174= | Silent (SNP) | VAF 48/476 reads (10%) | called by muse, mutect2
- PTCD2 | c.867G>C p.L289= | Silent (SNP) | VAF 12/140 reads (9%) | called by muse, mutect2
- RAC1 | c.90A>G p.G30= | Silent (SNP) | VAF 14/148 reads (9%) | called by muse, mutect2
- RBM42 | c.738A>G p.K246= | Silent (SNP) | VAF 4/40 reads (10%) | called by muse, mutect2
- RFPL3 | c.513C>A p.G171= (on ENST00000249007 / NM_001098535.1; = p.G142= on NM_006604.2) | Silent (SNP) | VAF 31/279 reads (11%) | called by muse, mutect2, varscan2
- RIMS2 | c.1566G>A p.T522= (on ENST00000666250 / NM_001348490.2; = p.T330= on NM_014677.5 and 7 other RefSeq transcripts) | Silent (SNP) | VAF 70/162 reads (43%) | catalogued as rs1157732703, COSV51721068, COSV99192726; called by muse, mutect2, varscan2
- RP1L1 | c.1056C>G p.A352= | Silent (SNP) | VAF 45/175 reads (26%) | called by muse, mutect2, varscan2
- RYR2 | c.4761C>T p.H1587= | Silent (SNP) | VAF 84/283 reads (30%) | catalogued as rs369612535; ClinVar: likely benign; called by muse, mutect2, varscan2
- RYR2 | c.5094G>T p.L1698= | Silent (SNP) | VAF 101/371 reads (27%) | catalogued as COSV100767369; called by muse, mutect2, varscan2
- RYR2 | c.9492T>G p.G3164= | Silent (SNP) | VAF 35/259 reads (14%) | catalogued as rs1252667379; called by muse, mutect2, varscan2
- SACS | c.1998G>T p.L666= | Silent (SNP) | VAF 38/140 reads (27%) | called by muse, mutect2, varscan2
- SAMSN1 | c.462G>A p.L154= | Silent (SNP) | VAF 66/446 reads (15%) | called by muse, mutect2, varscan2
- SCAP | c.3741C>A p.A1247= | Silent (SNP) | VAF 77/377 reads (20%) | called by muse, mutect2, varscan2
- SCN1A | c.2532G>C p.L844= (on ENST00000303395 / NM_001202435.3; = p.L833= on NM_006920.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 70/311 reads (23%) | called by muse, varscan2
- SDK1 | c.4161C>T p.P1387= | Silent (SNP) | VAF 46/284 reads (16%) | catalogued as rs778564851, COSV67388025; called by muse, mutect2, varscan2
- SHANK1 | c.5481G>A p.L1827= | Silent (SNP) | VAF 16/519 reads (3%) | called by muse, mutect2
- SLC13A1 | c.1056C>G p.V352= | Silent (SNP) | VAF 54/388 reads (14%) | called by muse, mutect2, varscan2
- SLIT3 | c.2976G>C p.R992= | Silent (SNP) | VAF 58/362 reads (16%) | catalogued as COSV100267949; called by muse, mutect2, varscan2
- TBX3 | c.168G>C p.L56= | Silent (SNP) | VAF 108/190 reads (57%) | called by muse, mutect2, varscan2
- TIAM1 | c.588C>T p.N196= | Silent (SNP) | VAF 24/346 reads (7%) | catalogued as rs753826634; called by muse, mutect2
- TMEM204 | c.624C>A p.S208= | Silent (SNP) | VAF 70/298 reads (23%) | catalogued as COSV54153762; called by muse, mutect2, varscan2
- TRADD | c.171C>T p.D57= | Silent (SNP) | VAF 22/151 reads (15%) | called by muse, mutect2, varscan2
- TTN | c.3030C>T p.S1010= (on ENST00000591111; = p.S964= on NM_003319.4) | Silent (SNP) | VAF 35/271 reads (13%) | catalogued as rs374346637; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- UMODL1 | c.2052T>C p.S684= (on ENST00000408910 / NM_001004416.2; = p.S812= on NM_173568.3) | Silent (SNP) | VAF 23/159 reads (14%) | called by muse, mutect2, varscan2
- USH2A | c.3219C>T p.S1073= | Silent (SNP) | VAF 30/322 reads (9%) | called by muse, mutect2
- XIRP1 | c.2112G>A p.E704= | Silent (SNP) | VAF 9/49 reads (18%) | catalogued as rs765991764; called by muse, mutect2
- ZDBF2 | c.6333G>A p.P2111= | Silent (SNP) | VAF 14/206 reads (7%) | catalogued as rs748503293, COSV65627358; called by muse, mutect2
- ZNF33B | c.1362A>T p.S454= | Silent (SNP) | VAF 18/174 reads (10%) | called by muse, mutect2, varscan2
- ZNF512 | c.399G>A p.Q133= | Silent (SNP) | VAF 45/408 reads (11%) | called by muse, mutect2, varscan2
- ABCD4 | c.668+54_668+92del | Intron (DEL) | VAF 34/162 reads (21%) | called by mutect2, pindel
- ADAMTS2 | c.1629+1032A>T | Intron (SNP) | VAF 13/71 reads (18%) | called by muse, mutect2, varscan2
- APOOP5 | n.230C>T | RNA (SNP) | VAF 10/256 reads (4%) | called by muse, mutect2
- ARHGAP33 | c.502-239G>T | Intron (SNP) | VAF 8/102 reads (8%) | called by muse, mutect2
- C18orf54 | c.589+285C>T | Intron (SNP) | VAF 6/134 reads (4%) | called by muse, mutect2
- CAPG | c.*65T>C | 3'UTR (SNP) | VAF 57/345 reads (17%) | called by muse, mutect2, varscan2
- CCDC89 | chr11:85682800 C>A | 3'Flank (SNP) | VAF 11/290 reads (4%) | called by muse, mutect2
- CD40LG | c.*23G>A | 3'UTR (SNP) | VAF 30/146 reads (21%) | called by muse, mutect2, varscan2
- CENPK | c.241+341G>T | Intron (SNP) | VAF 28/130 reads (22%) | called by muse, mutect2, varscan2
- CGA | c.-3G>A | 5'UTR (SNP) | VAF 5/82 reads (6%) | catalogued as rs1345017826, COSV63645127; called by muse, mutect2
- CNN2 | chr19:1026586 del C | 5'Flank (DEL) | VAF 14/62 reads (23%) | called by mutect2, pindel, varscan2
- CNTNAP3P2 | n.1017G>A | RNA (SNP) | VAF 48/250 reads (19%) | called by muse, mutect2, varscan2
- COLEC11 | c.-66G>C | 5'UTR (SNP) | VAF 5/38 reads (13%) | called by muse, mutect2, varscan2
- COLEC11 | c.130+1750del | Intron (DEL) | VAF 56/276 reads (20%) | called by mutect2, pindel, varscan2
- CPLANE1 | c.*2903G>A | 3'UTR (SNP) | VAF 7/154 reads (5%) | called by muse, mutect2
- CYP2A7P2 | n.292G>C | RNA (SNP) | VAF 28/194 reads (14%) | called by muse, mutect2, varscan2
- DCHS2 | n.7530G>T | RNA (SNP) | VAF 15/246 reads (6%) | catalogued as COSV61780212; called by muse, mutect2
- DCHS2 | n.7529A>T | RNA (SNP) | VAF 15/245 reads (6%) | called by muse, mutect2
- DIP2C | c.85+38283G>C | Intron (SNP) | VAF 99/674 reads (15%) | called by muse, mutect2, varscan2
- DOCK8 | c.741+48G>T | Intron (SNP) | VAF 9/223 reads (4%) | called by muse, mutect2
- ECM1 | c.708+15T>G | Intron (SNP) | VAF 14/426 reads (3%) | called by muse, mutect2
- FHOD3 | c.1197-5302G>T | Intron (SNP) | VAF 59/407 reads (14%) | called by muse, mutect2, varscan2
- FLT1 | c.-48G>T | 5'UTR (SNP) | VAF 80/226 reads (35%) | called by muse, mutect2, varscan2
- GPR89A | c.42+222A>G | Intron (SNP) | VAF 16/76 reads (21%) | catalogued as rs1341268739; called by muse, mutect2, varscan2
- GSTM2P1 | n.603C>T | RNA (SNP) | VAF 44/279 reads (16%) | called by muse, mutect2, varscan2
- HAUS2 | c.257-488A>T | Intron (SNP) | VAF 47/185 reads (25%) | called by muse, mutect2, varscan2
- HDAC9 | c.2369+18T>A | Intron (SNP) | VAF 34/342 reads (10%) | called by muse, mutect2
- KCNU1 | c.2736+408C>A | Intron (SNP) | VAF 7/182 reads (4%) | called by muse, mutect2
- KNDC1 | c.3579+31G>T | Intron (SNP) | VAF 23/202 reads (11%) | catalogued as COSV100463176; called by muse, mutect2, varscan2
- KRTAP20-4 | c.-30C>A | 5'UTR (SNP) | VAF 41/394 reads (10%) | called by muse, mutect2, varscan2
- MYBPH | c.*27A>G | 3'UTR (SNP) | VAF 92/397 reads (23%) | called by muse, mutect2, varscan2
- PACRG | c.614-67805G>T | Intron (SNP) | VAF 9/69 reads (13%) | called by muse, mutect2
- PARGP1 | n.1304C>T | RNA (SNP) | VAF 203/793 reads (26%) | called by muse, mutect2, varscan2
- PARP1 | c.287-33G>T | Intron (SNP) | VAF 121/430 reads (28%) | called by muse, mutect2, varscan2
- PIGS | c.1081-277G>T | Intron (SNP) | VAF 19/123 reads (15%) | called by muse, mutect2, varscan2
- PIN1 | c.58+34G>C | Intron (SNP) | VAF 18/61 reads (30%) | called by muse, mutect2, varscan2
- PRKAG2 | c.1585-24C>T | Intron (SNP) | VAF 37/272 reads (14%) | catalogued as rs553107117; called by muse, mutect2, varscan2
- PRKG1 | c.478+146250C>A | Intron (SNP) | VAF 51/362 reads (14%) | called by muse, mutect2, varscan2
- QSOX1 | c.*1259G>A | 3'UTR (SNP) | VAF 11/270 reads (4%) | called by muse, mutect2
- RBM5 | c.-4G>A | 5'UTR (SNP) | VAF 31/273 reads (11%) | called by muse, mutect2, varscan2
- RTBDN | c.462+155C>A | Intron (SNP) | VAF 4/23 reads (17%) | called by muse, mutect2, varscan2
- SETD7 | c.*72G>C | 3'UTR (SNP) | VAF 23/222 reads (10%) | called by muse, mutect2, varscan2
- SLC1A3 | c.1095-31C>A | Intron (SNP) | VAF 96/353 reads (27%) | called by muse, mutect2, varscan2
- SLC9A6 | c.1552-33A>G | Intron (SNP) | VAF 56/85 reads (66%) | catalogued as rs986982017; called by muse, mutect2, varscan2
- SPATA31C2 | n.1822del | RNA (DEL) | VAF 63/514 reads (12%) | catalogued as rs1563962083; called by mutect2, pindel, varscan2
- SPATA31C2 | n.1580del | RNA (DEL) | VAF 96/735 reads (13%) | called by mutect2, pindel, varscan2
- SRGAP2 | c.2505-221A>G | Intron (SNP) | VAF 49/278 reads (18%) | called by muse, mutect2, varscan2
- TDP1 | c.1753+75G>T | Intron (SNP) | VAF 99/393 reads (25%) | called by muse, mutect2, varscan2
- TG | c.5549-1633C>T | Intron (SNP) | VAF 13/217 reads (6%) | called by muse, mutect2
- TRAF3 | c.570+44A>G | Intron (SNP) | VAF 71/315 reads (23%) | called by muse, mutect2, varscan2
- USP17L30 | chr4:9369060 C>A | 3'Flank (SNP) | VAF 74/441 reads (17%) | called by muse, mutect2, varscan2
- VCX3A | c.*6C>A | 3'UTR (SNP) | VAF 242/516 reads (47%) | called by muse, varscan2
- VSIG10L | c.*78G>T | 3'UTR (SNP) | VAF 29/280 reads (10%) | catalogued as COSV99570641; called by muse, mutect2, varscan2
- ZNF606 | c.-165G>A | 5'UTR (SNP) | VAF 17/128 reads (13%) | called by muse, mutect2, varscan2
- ZNF695 | c.259+3312C>A | Intron (SNP) | VAF 62/218 reads (28%) | called by muse, varscan2
- ZNF721 | c.-3+26474C>T | Intron (SNP) | VAF 49/216 reads (23%) | called by muse, mutect2, varscan2
- ZNF890P | n.1052A>G | RNA (SNP) | VAF 4/25 reads (16%) | catalogued as rs1371340515; called by muse, mutect2
